Somatic mutation profile of tumor specimen TARGET-10-PANVJI-09A (aliquot TARGET-10-PANVJI-09A-01D) from TARGET case TARGET-10-PANVJI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,257 days).
Specimen TARGET-10-PANVJI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12f0bf72-ea43-4250-b36e-c009994c22c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANVJI-10A (Blood Derived Normal), aliquot TARGET-10-PANVJI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/303b6b44-d7ad-41d3-99de-0dd75afb651d

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, 3'UTR 1, Frame Shift Del 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAD50 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370769989, COSV54748170; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- GIPC2 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs143579527; called by muse, mutect2, varscan2
- NDST3 | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs150758016; called by muse, mutect2, varscan2
- ZC2HC1A | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs148584360; called by muse, mutect2, varscan2
- H2AC11 | c.331_357delinsT p.N111* | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | called by pindel, varscan2*
- IGKJ2 | chr2:88861539 TTGGTCCCCTGGCCAAAACTGCACACACAATGG>CT | Missense Mutation (DEL) | VAF 49/68 reads (72%) | called by pindel, varscan2*
- FDPS | c.735C>T p.P245= | Silent (SNP) | VAF 22/80 reads (28%) | called by muse, mutect2, varscan2
- AOC4P | n.2199C>T | RNA (SNP) | VAF 22/54 reads (41%) | catalogued as rs962499353; called by muse, mutect2, varscan2
- KCNE4 | c.*162G>A | 3'UTR (SNP) | VAF 12/26 reads (46%) | called by mutect2, varscan2
- KCTD1 | c.-15-45928C>T | Intron (SNP) | VAF 12/40 reads (30%) | catalogued as rs1316586092; called by muse, mutect2, varscan2
